Somatic mutation profile of tumor specimen TCGA-94-8490-01A (aliquot TCGA-94-8490-01A-11D-2323-08) from TCGA case TCGA-94-8490, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 70.1 years (25,588 days).
Specimen TCGA-94-8490-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 896ea498-728a-402d-aa90-2036e7de276b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-94-8490-10A (Blood Derived Normal), aliquot TCGA-94-8490-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/697c5b95-eb8c-4cff-ad66-f5c4f2648c4e

The open-access MAF lists 1,061 somatic variants for this specimen: 792 protein-altering or splice-affecting, 241 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 627, Silent 241, Frame Shift Ins 73, Frame Shift Del 35, Nonsense Mutation 29, Intron 15, Splice Site 15, Splice Region 6, RNA 6, 5'Flank 3, 5'UTR 3, Nonstop Mutation 3.

Variants (750 of 1,061; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934dup p.G646Wfs*12 | Frame Shift Ins (INS) | VAF 18/53 reads (34%) | hotspot (GDC flag); catalogued as rs750318549, COSV60102510; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AXIN2 | c.1994dup p.N666Qfs*41 | Frame Shift Ins (INS) | VAF 53/154 reads (34%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- HIBCH | c.129dup p.G44Rfs*20 | Frame Shift Ins (INS) | VAF 32/91 reads (35%) | catalogued as rs767597690; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 148/336 reads (44%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- A4GALT | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 144/416 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs142381337; called by muse, mutect2, varscan2
- AAR2 | c.686G>A p.S229N | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as rs1445551908, COSV100299364; called by muse, mutect2, varscan2
- AATK | c.3394C>T p.R1132W (on ENST00000326724 / NM_001080395.3; = p.R1029W on NM_004920.2) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs748897440, COSV100352993; called by muse, varscan2
- ABCA7 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99566249; called by muse, mutect2, varscan2
- ABCA8 | c.2720G>C p.R907T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV52206976, COSV99286337; called by muse, mutect2
- ABCA8 | c.1133A>G p.H378R | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99286341; called by muse, mutect2, varscan2
- ABCB5 | c.2005A>G p.K669E (on ENST00000404938 / NM_001163941.2; = p.K224E on NM_178559.6) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV99328903; called by muse, mutect2, varscan2
- ABCC10 | c.1511C>T p.A504V (on ENST00000372530 / NM_001198934.2; = p.A461V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543886430, COSV55084501; called by muse, mutect2, varscan2
- ABCD1 | c.1499G>A p.G500D | Missense Mutation (SNP) | VAF 122/148 reads (82%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as CM107817, COSV54387796; called by muse, varscan2
- ABCF3 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774957824, COSV53054298; called by muse, mutect2, varscan2
- ABHD13 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as rs770118849, COSV101024008, COSV101024212; called by muse, mutect2, varscan2
- ABHD16A | c.1250+2T>C p.X417_splice | Splice Site (SNP) | VAF 11/127 reads (9%) | catalogued as COSV101013261; called by muse, mutect2
- ABRAXAS1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 86/256 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748680448, COSV100426792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC018630.4 | c.314A>T p.Q105L | Missense Mutation (SNP) | VAF 208/585 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.257); catalogued as COSV99958551; called by muse, varscan2
- ACAT2 | c.339T>G p.I113M | Missense Mutation (SNP) | VAF 97/229 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100887166; called by muse, mutect2, varscan2
- ACSM3 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as COSV99184726; called by muse, mutect2
- ACTR6 | c.308C>A p.T103N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV99498686; called by muse, mutect2, varscan2
- ADCY5 | c.178dup p.A60Gfs*27 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | catalogued as rs756172692; called by mutect2, varscan2
- ADCY8 | c.3278A>G p.H1093R | Missense Mutation (SNP) | VAF 112/343 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99653115; called by muse, mutect2, varscan2
- ADGRB3 | c.3712T>A p.S1238T | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV99486043; called by muse, mutect2, varscan2
- AGBL2 | c.2252dup p.K752Efs*6 | Frame Shift Ins (INS) | VAF 34/64 reads (53%) | catalogued as rs776595317; called by mutect2, varscan2
- AHNAK | c.6119A>G p.H2040R | Missense Mutation (SNP) | VAF 93/1217 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99948416; called by muse, mutect2
- AK5 | c.1073T>G p.L358* (on ENST00000354567 / NM_174858.3; = p.L332* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 37/67 reads (55%) | catalogued as COSV100643122; called by muse, mutect2, varscan2
- AKAP8 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs1293704113, COSV99512027; called by muse, mutect2, varscan2
- AL121899.2 | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 528/779 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs772149238, COSV101198558, COSV67349773; called by muse, mutect2, varscan2
- ALG8 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100220180; called by muse, mutect2, varscan2
- ALPP | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1391511535, COSV101235166; called by muse, mutect2, varscan2
- AMDHD1 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 165/451 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372245131, COSV57140703, COSV99900400; called by muse, mutect2, varscan2
- ANKIB1 | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.406); catalogued as COSV99729446; called by muse, mutect2
- ANKRD12 | c.4140G>T p.K1380N | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV100041646; called by muse, mutect2
- ANKRD17 | c.4156A>G p.K1386E | Missense Mutation (SNP) | VAF 34/417 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100429558; called by muse, mutect2
- ANKRD42 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99473965; called by muse, mutect2, varscan2
- ANKRD50 | c.2000G>A p.G667D | Missense Mutation (SNP) | VAF 105/290 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1007230668, COSV101538996; called by muse, mutect2, varscan2
- ANKRD7 | c.737G>T p.S246I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV99501223; called by muse, mutect2, varscan2
- ANO1 | c.1713C>G p.I571M | Missense Mutation (SNP) | VAF 105/274 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100304224; called by muse, mutect2, varscan2
- AP002512.3 | c.728T>G p.V243G | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV99688029; called by muse, mutect2, varscan2
- AP1B1 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773941143, COSV100434666, COSV58016003; called by muse, mutect2, varscan2
- AP3M1 | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as COSV99281062; called by muse, mutect2, varscan2
- APC2 | c.5056T>G p.W1686G | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99279634; called by muse, mutect2, varscan2
- APOBR | c.1472G>T p.S491I (on ENST00000431282; = p.S500I on NM_018690.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV100112704; called by muse, mutect2, varscan2
- ARFGEF1 | c.3551G>C p.W1184S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99143145; called by muse, mutect2, varscan2
- ARHGAP45 | c.273C>A p.H91Q | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV99566250; called by muse, mutect2, varscan2
- ARHGAP45 | c.274C>G p.R92G | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99566253; called by muse, mutect2, varscan2
- ARHGAP9 | c.141_142insT p.G48Wfs*3 | Frame Shift Ins (INS) | VAF 109/320 reads (34%) | catalogued as COSV100712483; called by mutect2, pindel, varscan2
- ARHGEF17 | c.1850dup p.G618Wfs*4 | Frame Shift Ins (INS) | VAF 72/184 reads (39%) | catalogued as rs761146124; called by mutect2, varscan2
- ARHGEF26 | c.440dup p.R148Afs*4 | Frame Shift Ins (INS) | VAF 36/174 reads (21%) | catalogued as rs752791092; called by mutect2, pindel, varscan2
- ARMC5 | c.482T>G p.I161S | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51658560, COSV99192632; called by muse, mutect2, varscan2
- ART1 | c.344G>C p.G115A | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.88); PolyPhen benign (0.172); catalogued as COSV99167200, COSV99167272; called by muse, mutect2, varscan2
- ART1 | c.553C>A p.R185S | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV99167202; called by muse, mutect2, varscan2
- ART3 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100587859; called by muse, mutect2, varscan2
- ASAP2 | c.2357dup p.L787Afs*16 | Frame Shift Ins (INS) | VAF 38/150 reads (25%) | catalogued as rs773893016; called by mutect2, varscan2
- ASPHD1 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs558205057, COSV100435615; called by muse, mutect2
- ASXL2 | c.3208C>G p.L1070V | Missense Mutation (SNP) | VAF 71/238 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV99711626; called by muse, mutect2, varscan2
- ATL2 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248189669, COSV60052406, COSV60053137; called by muse, mutect2, varscan2
- ATL3 | c.176A>C p.D59A | Missense Mutation (SNP) | VAF 107/284 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as COSV100219917; called by muse, mutect2, varscan2
- ATM | c.6424A>G p.T2142A | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1263398076, COSV99590455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP13A1 | c.3451G>T p.G1151C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99179374; called by muse, mutect2, varscan2
- ATP13A3 | c.3079dup p.W1027Lfs*9 | Frame Shift Ins (INS) | VAF 45/182 reads (25%) | catalogued as rs746602775; called by mutect2, varscan2
- ATP1A2 | c.709A>T p.T237S | Missense Mutation (SNP) | VAF 110/177 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.346); catalogued as COSV100767991; called by muse, mutect2, varscan2
- ATP6V1A | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345641668, COSV99850227; called by muse, mutect2, varscan2
- ATP8B2 | c.3295G>C p.V1099L (on ENST00000672630; = p.V1066L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.379); catalogued as rs1209394978, COSV100874516; called by muse, mutect2, varscan2
- AVIL | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as COSV99142480; called by muse, mutect2, varscan2
- B3GALT5 | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 94/293 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.161); catalogued as COSV100563437, COSV100563496; called by muse, mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs771098505; called by mutect2, pindel, varscan2
- BACH1 | c.2071G>A p.G691S | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1569022838, COSV99727943, COSV99728427; called by muse, mutect2, varscan2
- BCAM | c.557A>C p.Y186S | Missense Mutation (SNP) | VAF 97/171 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV99538824; called by muse, mutect2, varscan2
- BCHE | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 55/288 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100012795; called by muse, mutect2, varscan2
- BEGAIN | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.363); catalogued as COSV100766994; called by muse, mutect2, varscan2
- BEND7 | c.826T>C p.S276P | Missense Mutation (SNP) | VAF 86/273 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100346824; called by muse, mutect2, varscan2
- BIRC6 | c.9086C>T p.A3029V | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV101428464; called by muse, mutect2, varscan2
- BRINP2 | c.1615G>C p.G539R | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100838194; called by muse, mutect2, varscan2
- BRPF3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 36/328 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV60208444; called by muse, mutect2, varscan2
- BST2 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 76/333 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99392102; called by muse, mutect2, varscan2
- BTAF1 | c.266A>T p.E89V | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV99795529; called by muse, mutect2, varscan2
- BZW1 | c.1146A>C p.K382N | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV100729875; called by muse, mutect2
- BZW2 | c.107_108insT p.Q36Hfs*4 | Frame Shift Ins (INS) | VAF 26/227 reads (11%) | catalogued as COSV99334723; called by mutect2, pindel, varscan2
- C11orf80 | c.1855T>C p.S619P | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV58992997; called by muse, mutect2, varscan2
- C14orf180 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100118786, COSV59557411; called by muse, mutect2, varscan2
- C20orf194 | c.401A>T p.E134V | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99331051; called by muse, mutect2, varscan2
- C2orf78 | c.1762A>G p.K588E | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.689); catalogued as COSV101281001; called by muse, mutect2, varscan2
- C2orf78 | c.1913A>G p.H638R | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101281002; called by muse, mutect2
- C5orf22 | c.1204A>G p.S402G | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100323567; called by muse, mutect2, varscan2
- C6orf118 | c.520A>T p.R174W | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100024751; called by muse, mutect2, varscan2
- CABIN1 | c.389T>G p.I130S | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99573458; called by muse, mutect2
- CACNA1C | c.2569C>A p.P857T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100220103; called by muse, mutect2, varscan2
- CACNA1I | c.5135G>A p.S1712N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100360859; called by muse, mutect2, varscan2
- CACNA1S | c.3686G>A p.R1229H | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs774416016, COSV62939289; called by muse, mutect2, varscan2
- CACYBP | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV100871630; called by muse, mutect2, varscan2
- CALB1 | c.440C>A p.T147K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99618387; called by muse, mutect2, varscan2
- CALR | c.302A>G p.Q101R | Missense Mutation (SNP) | VAF 173/468 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100330867; called by muse, mutect2, varscan2
- CALR | c.1198G>C p.D400H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as COSV100330868; called by muse, mutect2, varscan2
- CAMKMT | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 90/413 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101035072; called by muse, mutect2, varscan2
- CAPN15 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs765231833, COSV54837916; called by muse, mutect2, varscan2
- CARMIL3 | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 121/352 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs747792514, COSV57724594; called by muse, mutect2, varscan2
- CASP2 | c.1049A>G p.K350R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV100131130; called by muse, mutect2, varscan2
- CBLB | c.2737A>G p.T913A | Missense Mutation (SNP) | VAF 72/368 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.036); catalogued as COSV99913814; called by muse, mutect2, varscan2
- CBLIF | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99951019; called by muse, mutect2, varscan2
- CCDC148 | c.1260dup p.Y421Ifs*29 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | catalogued as rs761447262; called by mutect2, varscan2
- CCDC32 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100785980; called by muse, mutect2, varscan2
- CCDC96 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 259/474 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); catalogued as COSV100027993; called by muse, mutect2, varscan2
- CCNK | c.1078A>T p.T360S | Missense Mutation (SNP) | VAF 145/416 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV101110463; called by muse, mutect2, varscan2
- CCSER2 | c.227C>A p.A76E | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99826210; called by muse, mutect2, varscan2
- CD1D | c.323T>C p.L108S | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV63810164; called by muse, mutect2
- CD70 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 111/332 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99835613; called by muse, varscan2
- CDC42BPB | c.2053A>G p.K685E | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV100775516; called by muse, mutect2
- CDCA7 | c.533G>A p.R178H (on ENST00000347703 / NM_145810.3; = p.R257H on NM_031942.5) | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs764771856, COSV100143626; called by muse, mutect2, varscan2
- CDH23 | c.3565C>T p.R1189W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745855338, CM112923, COSV99822208; called by muse, mutect2, varscan2
- CDK5RAP3 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 111/350 reads (32%) | catalogued as COSV100621195; called by muse, mutect2, varscan2
- CDKL5 | c.614G>T p.S205I | Missense Mutation (SNP) | VAF 235/345 reads (68%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as COSV101184402; called by muse, mutect2, varscan2
- CELSR1 | c.6457G>T p.V2153L | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.523); catalogued as COSV53095886, COSV99419002; called by muse, mutect2, varscan2
- CEP70 | c.1295A>C p.N432T | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as COSV99389371; called by muse, mutect2
- CFAP46 | c.6791G>T p.R2264M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV99585176; called by muse, mutect2, varscan2
- CFAP52 | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 134/215 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100235380; called by muse, mutect2, varscan2
- CFH | c.2666A>C p.E889A | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100809855; called by muse, mutect2, varscan2
- CFTR | c.2231A>T p.Q744L | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99137614; called by muse, mutect2, varscan2
- CHD1L | c.1466T>C p.L489P | Missense Mutation (SNP) | VAF 81/359 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100787513; called by muse, mutect2, varscan2
- CHRND | c.1025T>A p.V342E | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.587); catalogued as COSV99285974; called by muse, mutect2
- CKMT2 | c.20A>T p.K7M | Missense Mutation (SNP) | VAF 176/261 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as COSV99562436; called by muse, mutect2, varscan2
- CLDN22 | c.597C>G p.Y199* | Nonsense Mutation (SNP) | VAF 27/372 reads (7%) | catalogued as rs200710817, COSV100032956, COSV60109234; called by muse, mutect2
- CLEC14A | c.896C>T p.T299I | Missense Mutation (SNP) | VAF 161/376 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV100643628; called by muse, mutect2, varscan2
- CLK1 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 82/317 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs764628118, COSV100362361; called by muse, mutect2, varscan2
- CLMN | c.1484dup p.L495Ffs*8 | Frame Shift Ins (INS) | VAF 37/101 reads (37%) | catalogued as rs1468470234; called by mutect2, varscan2
- CMTR1 | c.1835A>G p.Y612C | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100990890; called by muse, mutect2, varscan2
- CNOT11 | c.1416A>G p.I472M | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99179327; called by muse, varscan2
- CNOT3 | c.1156A>G p.T386A | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99652102; called by muse, mutect2
- CNPY2 | c.12G>T p.W4C | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99228376; called by muse, mutect2, varscan2
- CNST | c.647A>C p.E216A | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100829885; called by muse, mutect2, varscan2
- COBL | c.3239C>T p.T1080I | Missense Mutation (SNP) | VAF 27/316 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV99473270; called by muse, mutect2
- COG2 | c.380del p.K127Rfs*5 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as rs1188081815, COSV100794718; called by mutect2, varscan2
- COIL | c.485del p.N162Tfs*47 | Frame Shift Del (DEL) | VAF 88/268 reads (33%) | catalogued as rs769265872; called by mutect2, varscan2
- COL15A1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as rs138366672; called by muse, mutect2, varscan2
- COL3A1 | c.3029C>A p.P1010H | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100483345, COSV58590105; called by muse, mutect2
- COL4A4 | c.2234G>A p.G745D | Missense Mutation (SNP) | VAF 122/307 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61633431; called by muse, mutect2, varscan2
- COLEC12 | c.1740dup p.G581Rfs*17 | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | catalogued as rs750635929; called by mutect2, varscan2
- CRCT1 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | PolyPhen possibly damaging (0.873); catalogued as COSV100524289; called by muse, mutect2, varscan2
- CREB3L3 | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 51/130 reads (39%) | catalogued as COSV99314301; called by muse, mutect2, varscan2
- CRHBP | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs529618285, COSV99169507; called by muse, mutect2, varscan2
- CRTC1 | c.1713dup p.S572Qfs*4 | Frame Shift Ins (INS) | VAF 60/196 reads (31%) | catalogued as rs769538822; called by mutect2, varscan2
- CRYBG1 | c.4357G>A p.D1453N | Missense Mutation (SNP) | VAF 109/282 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs763237031, COSV100954565; called by muse, mutect2, varscan2
- CSMD3 | c.9452C>T p.S3151L (on ENST00000297405 / NM_001363185.1; = p.S2982L on NM_052900.3) | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.152); catalogued as COSV52182309, COSV99839634; called by muse, mutect2, varscan2
- CSMD3 | c.6917T>G p.F2306C (on ENST00000297405 / NM_001363185.1; = p.F2202C on NM_052900.3) | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as COSV99839636; called by muse, mutect2, varscan2
- CSMD3 | c.1707C>A p.D569E (on ENST00000297405 / NM_001363185.1; = p.D465E on NM_052900.3) | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.028); catalogued as COSV99839641; called by muse, varscan2
- CTDSP2 | c.690+2T>C p.X230_splice | Splice Site (SNP) | VAF 28/89 reads (31%) | catalogued as COSV101143037; called by muse, mutect2, varscan2
- CUBN | c.9428G>A p.W3143* | Nonsense Mutation (SNP) | VAF 27/424 reads (6%) | catalogued as rs1442285963, COSV100913066; called by muse, mutect2
- CWH43 | c.110T>A p.L37Q | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99893691; called by muse, mutect2, varscan2
- CXCL9 | c.355T>C p.S119P | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99345785; called by muse, mutect2, varscan2
- CXCR4 | c.1035G>T p.E345D | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.967); catalogued as COSV99603195; called by muse, mutect2, varscan2
- CYB561 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs76648903, COSV62540321; called by muse, mutect2, varscan2
- CYRIB | c.404T>A p.I135N | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV101310204; called by muse, mutect2, varscan2
- DAPK1 | c.447T>A p.D149E | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100802372; called by muse, mutect2, varscan2
- DBT | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 57/94 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100923743, COSV64497858; called by muse, mutect2, varscan2
- DCP1B | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs961338908, COSV99767671; called by muse, mutect2, varscan2
- DCPS | c.741G>T p.Q247H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV99703444; called by muse, varscan2
- DDB2 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1337293467, COSV99921708; called by muse, varscan2
- DDX60L | c.2252T>C p.L751P | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV99487940; called by muse, mutect2
- DENND2A | c.1440A>G p.I480M | Missense Mutation (SNP) | VAF 125/379 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV52060437; called by muse, mutect2, varscan2
- DENND4A | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101475381; called by muse, mutect2, varscan2
- DENND4B | c.2518C>T p.R840C | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs750915651, COSV100768785; called by muse, mutect2, varscan2
- DENND6A | c.1074dup p.A359Cfs*2 | Frame Shift Ins (INS) | VAF 33/68 reads (49%) | catalogued as rs34959359; called by mutect2, varscan2
- DGKB | c.2253C>A p.S751R | Missense Mutation (SNP) | VAF 98/326 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as rs759149020, COSV99341224; called by muse, mutect2, varscan2
- DGKI | c.1898G>T p.R633L | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99935804; called by muse, mutect2, varscan2
- DHX29 | c.3272T>C p.I1091T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52416902, COSV99287452; called by muse, mutect2
- DIDO1 | c.2029T>C p.S677P | Missense Mutation (SNP) | VAF 81/372 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99826386; called by muse, mutect2, varscan2
- DISP2 | c.4168C>T p.R1390C | Missense Mutation (SNP) | VAF 101/269 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs372879494; called by muse, mutect2, varscan2
- DMAP1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 66/106 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60001130; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH10 | c.3070T>C p.S1024P (on ENST00000409039; = p.S963P on NM_207437.3) | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV101292412; called by muse, mutect2, varscan2
- DNAH10 | c.3167G>T p.R1056L (on ENST00000409039; = p.R995L on NM_207437.3) | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV68992894; called by muse, mutect2
- DNAH3 | c.691C>A p.L231M | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV99768850; called by muse, mutect2, varscan2
- DNAH8 | c.7333A>G p.I2445V | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.268); catalogued as rs575966640, COSV100546276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC2 | c.1844A>G p.N615S | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as COSV99971325; called by muse, mutect2
- DNAJC21 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 127/167 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100331506; called by muse, mutect2, varscan2
- DNER | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100519532; called by muse, mutect2, varscan2
- DNMT1 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100532687; called by muse, mutect2, varscan2
- DPP4 | c.1364A>C p.Q455P | Missense Mutation (SNP) | VAF 81/292 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100858949; called by muse, mutect2, varscan2
- DPYSL5 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 160/554 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV99982550; called by muse, mutect2, varscan2
- DPYSL5 | c.407G>C p.W136S | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0.103); catalogued as COSV99982552; called by muse, mutect2, varscan2
- DRD3 | c.254G>T p.W85L | Missense Mutation (SNP) | VAF 109/606 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV99879540; called by muse, mutect2, varscan2
- DSTYK | c.2519A>G p.Y840C | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1308806650, COSV100904627; called by muse, mutect2
- DYM | c.22A>T p.I8F | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.81); catalogued as COSV99493601; called by muse, mutect2, varscan2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 48/116 reads (41%) | catalogued as rs751377941; called by mutect2, varscan2
- ECSIT | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.2); catalogued as rs1197585857, COSV99369137; called by muse, mutect2, varscan2
- EEF2 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58579797; called by muse, mutect2, varscan2
- EIF3H | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.138); catalogued as COSV99412075; called by muse, mutect2, varscan2
- EIF3M | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 110/179 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100025073; called by muse, mutect2, varscan2
- EIF5B | c.1253G>C p.R418T | Missense Mutation (SNP) | VAF 176/379 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV99177439; called by muse, mutect2, varscan2
- ELFN2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 88/196 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.069); catalogued as rs369242294; called by muse, mutect2, varscan2
- ELOVL4 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371760799; called by muse, mutect2, varscan2
- EN1 | c.1102C>A p.L368M | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99727165; called by muse, mutect2
- ENOX1 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 57/94 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1299385078, COSV54889073, COSV54914203; called by muse, mutect2, varscan2
- ENTHD1 | c.1169C>A p.A390E | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV100288920; called by muse, mutect2
- EP300 | c.4334A>G p.D1445G | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99609147; called by muse, mutect2, varscan2
- EPB41L4B | c.2135T>C p.V712A | Missense Mutation (SNP) | VAF 123/332 reads (37%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.089); catalogued as COSV100775846; called by muse, mutect2, varscan2
- EPB42 | c.722T>C p.L241S (on ENST00000441366 / NM_001114134.2; = p.L271S on NM_000119.3) | Missense Mutation (SNP) | VAF 94/247 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.043); catalogued as rs771882643, COSV100282060; called by muse, mutect2, varscan2
- EPC1 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 97/240 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV99553172; called by muse, mutect2, varscan2
- EPHA5 | c.1378G>T p.V460L | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99899948; called by muse, mutect2, varscan2
- ERICH3 | c.2633A>C p.K878T | Missense Mutation (SNP) | VAF 213/351 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100444968; called by muse, mutect2, varscan2
- ETFA | c.745C>G p.R249G | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1353938548, CM061729, COSV99144250; called by muse, mutect2, varscan2
- EVX2 | c.478T>C p.S160P | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100420747; called by muse, mutect2, varscan2
- EYS | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 109/295 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.057); catalogued as COSV60997451; called by muse, mutect2, varscan2
- F12 | c.798C>T p.C266= | Splice Region (SNP) | VAF 5/17 reads (29%) | catalogued as rs769787706, COSV99499817; called by muse, mutect2, varscan2
- F13A1 | c.436T>C p.S146P | Missense Mutation (SNP) | VAF 104/330 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV99343442; called by muse, mutect2, varscan2
- FABP4 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99073639, COSV99808575; called by muse, mutect2, varscan2
- FAM122A | c.736G>T p.G246* | Nonsense Mutation (SNP) | VAF 197/526 reads (37%) | catalogued as COSV99599286; called by muse, mutect2, varscan2
- FAM126A | c.774A>T p.K258N | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV101327201; called by muse, mutect2, varscan2
- FAM135B | c.1855G>T p.G619* | Nonsense Mutation (SNP) | VAF 112/306 reads (37%) | catalogued as COSV99425540; called by muse, mutect2, varscan2
- FAM214A | c.2849G>T p.R950L | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99958150; called by muse, mutect2, varscan2
- FAM83B | c.1685G>T p.G562V | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV60922037; called by muse, mutect2, varscan2
- FANCB | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 61/78 reads (78%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV100146625; called by muse, mutect2, varscan2
- FANCM | c.4305A>T p.L1435F | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99951282; called by muse, mutect2, varscan2
- FANCM | c.6145T>C p.*2049Qext*20 | Nonstop Mutation (SNP) | VAF 36/95 reads (38%) | catalogued as COSV99951285; called by muse, mutect2, varscan2
- FAP | c.920A>G p.Q307R | Missense Mutation (SNP) | VAF 114/360 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99502321; called by muse, varscan2
- FAT2 | c.9490G>A p.A3164T | Missense Mutation (SNP) | VAF 108/205 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.624); catalogued as rs200687536, COSV55822526; called by muse, mutect2, varscan2
- FAXC | c.620G>T p.W207L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as COSV101067182; called by muse, mutect2, varscan2
- FBLN5 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 107/305 reads (35%) | catalogued as COSV50906658, COSV99969743; called by muse, mutect2, varscan2
- FBN1 | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1555400280, COSV100355784; ClinVar: uncertain significance; called by muse, mutect2
- FBXL16 | c.854T>C p.L285P | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100179059; called by muse, mutect2, varscan2
- FBXL19 | c.2008T>C p.C670R | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100590988; called by muse, mutect2
- FER1L6 | c.1647T>G p.I549M | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV101206031; called by muse, mutect2, varscan2
- FER1L6 | c.4435A>T p.I1479F | Missense Mutation (SNP) | VAF 94/236 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV101206034; called by muse, mutect2, varscan2
- FGF6 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV99960323; called by muse, mutect2
- FOXP2 | c.1936A>C p.N646H | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100647069; called by muse, mutect2, varscan2
- FOXP4 | c.794C>T p.P265L (on ENST00000307972 / NM_001012426.1; = p.P264L on NM_138457.3) | Missense Mutation (SNP) | VAF 128/327 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs781448348, COSV100332846; called by muse, mutect2, varscan2
- FSCB | c.388A>G p.R130G | Missense Mutation (SNP) | VAF 156/419 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV100469530; called by muse, mutect2, varscan2
- FSHR | c.212A>G p.D71G | Missense Mutation (SNP) | VAF 178/355 reads (50%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.536); catalogued as COSV58621367; called by muse, mutect2, varscan2
- FTHL17 | c.331G>T p.V111F | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100784344, COSV63267174; called by muse, mutect2, varscan2
- GABRA1 | c.1059G>T p.K353N | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.311); catalogued as COSV99196085; called by muse, mutect2, varscan2
- GATA4 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM051506, COSV100632943; called by muse, mutect2, varscan2
- GATA6 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as COSV52528649; called by muse, mutect2, varscan2
- GBX1 | c.476A>G p.K159R | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.307); catalogued as COSV99880951; called by muse, mutect2, varscan2
- GC | c.149G>T p.R50I | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56739654, COSV99909919; called by muse, mutect2, varscan2
- GCFC2 | c.1880A>G p.Y627C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100319619, COSV58081065; called by muse, mutect2, varscan2
- GCLC | c.334G>C p.E112Q (on ENST00000643939; = p.E116Q on NM_001498.4) | Missense Mutation (SNP) | VAF 68/553 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV99988750; called by muse, mutect2, varscan2
- GFPT2 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV99517861; called by muse, mutect2, varscan2
- GLRA2 | c.776T>A p.I259N | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54339977; called by muse, varscan2
- GLUD1 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as COSV99518277; called by muse, mutect2, varscan2
- GMIP | c.430-2A>T p.X144_splice | Splice Site (SNP) | VAF 39/118 reads (33%) | catalogued as COSV99179373; called by muse, mutect2, varscan2
- GPC1 | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV99883027; called by muse, mutect2, varscan2
- GPR15 | c.357C>A p.C119* | Nonsense Mutation (SNP) | VAF 26/318 reads (8%) | catalogued as COSV99423848; called by muse, mutect2
- GPR65 | c.283T>C p.Y95H | Missense Mutation (SNP) | VAF 22/488 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as COSV99966106; called by muse, mutect2
- GPR85 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.67); catalogued as COSV99775231; called by muse, mutect2, varscan2
- GPS1 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as rs759446578, COSV57650335; called by muse, mutect2, varscan2
- GRAMD1B | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV100454938; called by muse, mutect2
- GRID1 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 292/755 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV100021698, COSV100025077; called by muse, mutect2, varscan2
- GRIK2 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV100027492; called by muse, mutect2, varscan2
- GRK3 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 22/174 reads (13%) | catalogued as COSV60793509; called by muse, mutect2, varscan2
- GRM5 | c.1957C>T p.L653F | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV100552477, COSV100553042; called by muse, mutect2, varscan2
- GTF2A1 | c.339C>T p.A113= | Splice Region (SNP) | VAF 34/96 reads (35%) | catalogued as COSV99993481; called by muse, mutect2, varscan2
- GYPC | c.374A>T p.E125V | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52146285; called by muse, mutect2, varscan2
- GZMH | c.612dup p.P205Afs*5 | Frame Shift Ins (INS) | VAF 60/268 reads (22%) | catalogued as rs770777921; called by mutect2, pindel, varscan2
- H2AC4 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 93/238 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as COSV99451586; called by muse, mutect2, varscan2
- HADH | c.164T>C p.L55S | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100531430; called by muse, mutect2, varscan2
- HAPLN1 | c.965G>C p.R322T | Missense Mutation (SNP) | VAF 219/335 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs889122618, COSV57145622, COSV99165050; called by muse, mutect2, varscan2
- HECW1 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 111/281 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs901083422, COSV67830670; called by muse, mutect2, varscan2
- HECW2 | c.2406C>A p.Y802* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99647859; called by muse, mutect2, varscan2
- HELQ | c.2929T>A p.C977S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99787896; called by muse, mutect2, varscan2
- HERC1 | c.9380T>C p.M3127T | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV101496717; called by muse, mutect2, varscan2
- HERC2 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.539); catalogued as rs779353738, COSV55333983, COSV99875177; called by muse, mutect2, varscan2
- HERPUD2 | c.1139G>C p.G380A | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV100258028; called by muse, mutect2, varscan2
- HES1 | c.32C>G p.S11W | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV51684917, COSV99220522; called by muse, mutect2, varscan2
- HGFAC | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs538101167, COSV100123099; called by muse, varscan2
- HHIP | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as COSV99667516; called by muse, mutect2, varscan2
- HMGXB4 | c.117T>A p.D39E | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99330175; called by muse, mutect2, varscan2
- HNF4G | c.1010A>T p.H337L (on ENST00000354370 / NM_001330561.2; = p.H384L on NM_004133.5) | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV100584754; called by muse, mutect2
- HNRNPH1 | c.796T>C p.Y266H | Missense Mutation (SNP) | VAF 72/111 reads (65%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.764); catalogued as COSV100270784; called by muse, mutect2, varscan2
- HSD17B2 | c.382T>C p.C128R | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99556726; called by muse, mutect2, varscan2
- HSPB11 | c.176T>A p.I59N | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99524031; called by muse, mutect2
- HSPB9 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV99863625; called by muse, mutect2, varscan2
- ICE1 | c.4355A>T p.Q1452L | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99665135; called by muse, mutect2, varscan2
- IDH3B | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 71/394 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.053); catalogued as COSV100250229, COSV104412313; called by muse, mutect2, varscan2
- IFT80 | c.832T>C p.S278P | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100424914; called by muse, mutect2, varscan2
- IGF2 | c.626A>T p.K209I (on ENST00000434045 / NM_001127598.3; = p.K153I on NM_000612.6) | Missense Mutation (SNP) | VAF 80/138 reads (58%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.536); catalogued as COSV100324137; called by muse, mutect2, varscan2
- IGHV1-3 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 169/388 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1555418951; called by muse, mutect2, varscan2
- IGSF9 | c.154dup p.L52Pfs*27 | Frame Shift Ins (INS) | VAF 28/176 reads (16%) | catalogued as rs753928344; called by mutect2, varscan2
- IHH | c.1132G>C p.G378R | Missense Mutation (SNP) | VAF 62/84 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV99838728; called by muse, mutect2, varscan2
- IL1RAP | c.1125T>G p.I375M | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV50761352, COSV99299939; called by muse, mutect2, varscan2
- IL1RAPL1 | c.475A>T p.S159C | Missense Mutation (SNP) | VAF 91/136 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100148320; called by muse, mutect2, varscan2
- IL36B | c.15G>A p.R5= | Splice Region (SNP) | VAF 15/143 reads (10%) | catalogued as rs141795577; called by muse, mutect2, varscan2
- IL7R | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs536561203, COSV57407250; called by muse, mutect2, varscan2
- IMP4 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1317695562, COSV99383786; called by muse, mutect2, varscan2
- INHBA | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54221290, COSV99637953; called by muse, mutect2, varscan2
- INPP5F | c.1871T>C p.I624T | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs1457638274, COSV100740253; called by muse, mutect2, varscan2
- INTS8 | c.1165A>G p.T389A | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100569337; called by muse, mutect2, varscan2
- IQCB1 | c.100+1G>A p.X34_splice | Splice Site (SNP) | VAF 93/141 reads (66%) | catalogued as COSV100182015; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.293A>G p.D98G (on ENST00000485419 / NM_001197113.1; = p.D22G on NM_014575.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs961962373, COSV100541431, COSV61862395; called by muse, mutect2, varscan2
- IRAK4 | c.1181A>C p.Q394P | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV71210277; called by muse, mutect2
- IRX2 | c.493T>C p.F165L | Missense Mutation (SNP) | VAF 130/390 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121813; called by muse, mutect2, varscan2
- ITGA10 | c.2690A>T p.E897V | Missense Mutation (SNP) | VAF 748/1178 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65196024; called by muse, mutect2, varscan2
- ITGA3 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs546685892, COSV50306170, COSV99143853; called by muse, mutect2, varscan2
- ITGAL | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100776291; called by muse, mutect2, varscan2
- ITGAV | c.847-1G>T p.X283_splice | Splice Site (SNP) | VAF 31/142 reads (22%) | catalogued as COSV53713475; called by muse, mutect2, varscan2
- ITGB3 | c.502A>G p.M168V | Missense Mutation (SNP) | VAF 132/327 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV101457640; called by muse, mutect2, varscan2
- ITPR2 | c.5105G>A p.R1702Q | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs925579137, COSV67271466; called by muse, mutect2, varscan2
- ITPRID1 | c.3047C>T p.S1016F | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs766994364, COSV100086907; called by muse, mutect2, varscan2
- JHY | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 186/522 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56219384, COSV99913458; called by muse, mutect2, varscan2
- JPH1 | c.1748A>G p.K583R | Missense Mutation (SNP) | VAF 191/458 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100646680; called by muse, mutect2, varscan2
- KANSL2 | c.146A>G p.H49R | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100771010, COSV63480235; called by muse, mutect2, varscan2
- KCNB2 | c.236A>G p.D79G | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV73053140; called by muse, mutect2, varscan2
- KCNC2 | c.575T>C p.I192T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.065); catalogued as rs1188167159, COSV100129283; called by muse, mutect2, varscan2
- KCNH7 | c.2720C>A p.T907K | Missense Mutation (SNP) | VAF 117/221 reads (53%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100148709; called by muse, mutect2, varscan2
- KCNK13 | c.1171dup p.V391Gfs*67 | Frame Shift Ins (INS) | VAF 14/95 reads (15%) | catalogued as rs766469179; called by mutect2, varscan2
- KCNT2 | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV99654232, COSV99655098; called by muse, mutect2, varscan2
- KCNV1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1438034311, COSV99819160; called by muse, mutect2, varscan2
- KCTD2 | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100483355; called by muse, mutect2, varscan2
- KDM5C | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855467, COSV62890930; called by muse, mutect2
- KEAP1 | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99407626; called by muse, mutect2, varscan2
- KIAA0319 | c.2709C>G p.F903L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100985675, COSV65498521; called by muse, mutect2, varscan2
- KIAA0895 | c.388T>C p.Y130H (on ENST00000297063 / NM_001100425.2; = p.Y79H on NM_015314.3) | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV99767001; called by muse, mutect2, varscan2
- KIF13A | c.4166A>C p.H1389P | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.222); catalogued as rs1044421319, COSV99436844; called by muse, mutect2, varscan2
- KIF15 | c.3517T>G p.L1173V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV100392987; called by muse, mutect2
- KIF16B | c.3426T>G p.S1142R | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV100734622; called by muse, mutect2, varscan2
- KIF18A | c.1801T>C p.F601L | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV54185551, COSV99588892; called by muse, mutect2, varscan2
- KIF26B | c.2086G>T p.G696W | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100832841; called by muse, mutect2, varscan2
- KIF5A | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as rs767181570, COSV54055467; called by muse, mutect2, varscan2
- KIFAP3 | c.1117T>C p.F373L | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs772431741, COSV100810955; called by muse, mutect2, varscan2
- KIR2DL1 | c.932C>T p.T311I | Missense Mutation (SNP) | VAF 281/476 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs773140522; called by muse, mutect2, varscan2
- KIR2DL3 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 44/709 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs1174321807, COSV60899427; called by muse, mutect2
- KLHL1 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs565048506, COSV100917672; called by muse, mutect2, varscan2
- KLHL18 | c.483C>A p.S161R | Missense Mutation (SNP) | VAF 89/144 reads (62%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99231094; called by muse, mutect2, varscan2
- KLHL32 | c.1203T>A p.Y401* | Nonsense Mutation (SNP) | VAF 20/125 reads (16%) | catalogued as COSV100987409; called by muse, mutect2, varscan2
- KLHL4 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV100909973, COSV100910137; called by muse, mutect2, varscan2
- KLHL4 | c.617A>T p.Y206F | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100909974; called by muse, mutect2, varscan2
- KLHL42 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 108/296 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101179806; called by muse, mutect2, varscan2
- KLHL9 | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 101/273 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100757136; called by muse, mutect2, varscan2
- KMT2A | c.9562G>T p.V3188F | Missense Mutation (SNP) | VAF 32/355 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV100629257; called by muse, mutect2
- KMT2C | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.857); catalogued as COSV100074042; called by muse, mutect2, varscan2
- KMT2D | c.12493C>T p.Q4165* | Nonsense Mutation (SNP) | VAF 77/175 reads (44%) | catalogued as COSV99983759; called by muse, mutect2, varscan2
- KNDC1 | c.5209A>T p.I1737F | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV100465529; called by muse, mutect2, varscan2
- KRT5 | c.1447G>T p.G483* | Nonsense Mutation (SNP) | VAF 35/104 reads (34%) | catalogued as COSV99358119; called by muse, mutect2, varscan2
- KRTAP12-2 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as rs200410263; called by muse, mutect2
- KRTAP19-7 | c.191G>C p.*64Sext*4 | Nonstop Mutation (SNP) | VAF 121/320 reads (38%) | catalogued as COSV100603215; called by muse, mutect2, varscan2
- KRTAP26-1 | c.571A>G p.S191G | Missense Mutation (SNP) | VAF 47/571 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100860443, COSV62129469; called by muse, mutect2
- KRTAP4-4 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 125/330 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs943933243, COSV66811633; called by mutect2, varscan2
- L3MBTL2 | c.2086G>C p.V696L | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99345986; called by muse, mutect2, varscan2
- LAMA4 | c.3881A>G p.D1294G (on ENST00000230538 / NM_001105206.3; = p.D1287G on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100038852; called by muse, mutect2
- LAMA5 | c.2372A>G p.Q791R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as COSV99441041; called by muse, mutect2, varscan2
- LAMB4 | c.181A>G p.S61G | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.018); catalogued as COSV99224791; called by muse, mutect2, varscan2
- LAMC2 | c.1590T>A p.N530K | Missense Mutation (SNP) | VAF 86/434 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV99917647; called by muse, mutect2, varscan2
- LANCL1 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 81/241 reads (34%) | catalogued as rs980649959, COSV52063950; called by muse, mutect2, varscan2
- LARS2 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs142506388; called by muse, mutect2, varscan2
- LAS1L | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 145/193 reads (75%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV100408622; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 51/106 reads (48%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LHCGR | c.774dup p.L259Ifs*25 | Frame Shift Ins (INS) | VAF 44/175 reads (25%) | catalogued as rs764644774; called by mutect2, varscan2
- LHX1 | c.1194dup p.E399Rfs*65 | Frame Shift Ins (INS) | VAF 20/70 reads (29%) | catalogued as rs775423572; called by mutect2, varscan2
- LMNTD1 | c.871A>T p.T291S | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV99280025; called by muse, mutect2, varscan2
- LPP | c.1472C>A p.T491N | Missense Mutation (SNP) | VAF 85/447 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100447177, COSV100447812; called by muse, mutect2, varscan2
- LRCH3 | c.2086C>T p.R696* | Nonsense Mutation (SNP) | VAF 180/971 reads (19%) | catalogued as rs1202774397, COSV100605170; called by muse, mutect2, varscan2
- LRP12 | c.2498A>G p.H833R | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV52631580; called by muse, mutect2
- LRP1B | c.10532-2A>T p.X3511_splice | Splice Site (SNP) | VAF 30/111 reads (27%) | catalogued as COSV101258021, COSV101262248; called by muse, mutect2, varscan2
- LRP1B | c.9120+2T>C p.X3040_splice | Splice Site (SNP) | VAF 12/231 reads (5%) | catalogued as COSV101258022; called by muse, mutect2
- LRP1B | c.2233T>C p.S745P | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as COSV101258023; called by muse, mutect2, varscan2
- LRP2 | c.1006T>C p.Y336H | Missense Mutation (SNP) | VAF 102/339 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs946025655, COSV99789402; called by muse, mutect2, varscan2
- LRRC34 | c.203T>G p.I68S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.112); catalogued as COSV100336370; called by muse, mutect2, varscan2
- LRRC36 | c.23A>G p.D8G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV100326171; called by muse, mutect2
- LRRC52 | c.577C>A p.L193M | Missense Mutation (SNP) | VAF 37/633 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV99673976; called by muse, mutect2
- LRRIQ1 | c.3380A>G p.D1127G | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV101280629; called by muse, mutect2, varscan2
- LRRK1 | c.5903A>G p.D1968G | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as COSV52603556, COSV99441388; called by muse, mutect2, varscan2
- LRRK2 | c.6761C>T p.S2254F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.125); catalogued as COSV100110724; called by muse, mutect2, varscan2
- LRRTM1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV54448532, COSV99702817; called by muse, mutect2, varscan2
- LRRTM1 | c.513C>A p.N171K | Missense Mutation (SNP) | VAF 156/288 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54444317, COSV99702818; called by muse, varscan2
- LTB4R | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.324); catalogued as COSV100156689; called by muse, mutect2, varscan2
- LUC7L3 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV99537025; called by muse, mutect2, varscan2
- LYN | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 90/235 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as rs376329765; called by muse, mutect2, varscan2
- LYST | c.2438G>A p.R813Q | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs558162561, COSV67703188, COSV67703578; called by muse, mutect2, varscan2
- MAGEC1 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 100/134 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV99596034; called by muse, mutect2, varscan2
- MAMDC4 | c.2912-2A>T p.X971_splice (on ENST00000445819; = p.X892_splice on NM_206920.3) | Splice Site (SNP) | VAF 17/153 reads (11%) | catalogued as COSV99808169; called by muse, mutect2, varscan2
- MAP2 | c.5230G>C p.D1744H | Missense Mutation (SNP) | VAF 82/115 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99560851; called by muse, mutect2, varscan2
- MAP3K4 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815518; called by muse, mutect2, varscan2
- MAP4K3 | c.1828A>G p.M610V | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV99810670; called by muse, mutect2, varscan2
- MAPK3 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV99531593; called by muse, mutect2, varscan2
- MAST1 | c.1377T>G p.C459W | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99263268; called by muse, mutect2, varscan2
- MAST3 | c.1732G>T p.V578L | Missense Mutation (SNP) | VAF 88/273 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV53217327, COSV99445757; called by muse, mutect2, varscan2
- MBL2 | c.370A>G p.K124E | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV100906369; called by muse, varscan2
- MCCC1 | c.837G>C p.Q279H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99659895; called by muse, mutect2, varscan2
- MCM10 | c.2464A>C p.S822R (on ENST00000484800 / NM_182751.3; = p.S821R on NM_018518.5) | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV101098259; called by muse, mutect2, varscan2
- MDM1 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 86/810 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100291950; called by muse, mutect2, varscan2
- MDN1 | c.6659G>A p.G2220D | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65519745; called by muse, mutect2, varscan2
- MED13L | c.2138A>G p.N713S | Missense Mutation (SNP) | VAF 137/363 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99929416; called by muse, mutect2, varscan2
- MED26 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs750096948, COSV99660073; called by muse, mutect2, varscan2
- MEN1 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1174189283, COSV99581270; called by muse, mutect2, varscan2
- METTL16 | c.791T>C p.I264T | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated (0.62); PolyPhen benign (0.065); catalogued as COSV99563565; called by muse, mutect2, varscan2
- METTL25 | c.1812A>G p.*604Wext*13 | Nonstop Mutation (SNP) | VAF 14/118 reads (12%) | catalogued as COSV99942506; called by mutect2, varscan2
- MGA | c.7388T>A p.I2463N (on ENST00000219905 / NM_001164273.1; = p.I2254N on NM_001080541.2) | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54949776; called by muse, mutect2, varscan2
- MLF1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 14/255 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100576027; called by muse, mutect2
- MLN | c.320A>C p.E107A | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV99803238; called by muse, mutect2, varscan2
- MLXIP | c.1804T>C p.S602P | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100038906, COSV100039284; called by muse, mutect2, varscan2
- MMP3 | c.298T>C p.F100L | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as COSV100242896, COSV100243022; called by muse, mutect2
- MN1 | c.3715G>A p.A1239T | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV56560418; called by muse, mutect2
- MPO | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs1326229205, COSV56566645; called by muse, mutect2, varscan2
- MPZL1 | c.258G>T p.S86= | Splice Region (SNP) | VAF 55/289 reads (19%) | catalogued as COSV100850379; called by muse, mutect2, varscan2
- MRPS5 | c.1046T>A p.L349H | Missense Mutation (SNP) | VAF 34/504 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99720893; called by muse, mutect2
- MTA1 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as rs146825093; called by muse, mutect2, varscan2
- MTHFD2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 74/353 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as rs774595885, COSV51201760; called by muse, mutect2, varscan2
- MUC16 | c.30925G>C p.E10309Q | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.133); catalogued as COSV101200443, COSV67477965; called by muse, mutect2
- MX2 | c.1042A>G p.T348A | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV100416032; called by muse, mutect2, varscan2
- MYCN | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.207); catalogued as rs372079635, COSV99808392; called by muse, mutect2, varscan2
- MYH3 | c.5619A>T p.Q1873H | Missense Mutation (SNP) | VAF 127/221 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99878497; called by muse, mutect2, varscan2
- MYH6 | c.1156G>T p.A386S | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100676783; called by muse, mutect2, varscan2
- MYH7 | c.3134G>A p.R1045H | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516178, CM094389, COSV100806075; called by muse, mutect2, varscan2
- MYO10 | c.1445A>G p.E482G | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as COSV101569820; called by muse, mutect2, varscan2
- MYOD1 | c.454A>G p.N152D | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV51452730; called by muse, mutect2, varscan2
- MYT1 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750742682, COSV100115028; called by muse, mutect2, varscan2
- NAALAD2 | c.1744A>G p.I582V | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100428619; called by muse, mutect2, varscan2
- NAV1 | c.2224A>T p.K742* | Nonsense Mutation (SNP) | VAF 72/182 reads (40%) | catalogued as COSV99819174; called by muse, mutect2
- NBAS | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs763005913, COSV55735406, COSV99870675; called by mutect2, varscan2
- NCAPD2 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.188); catalogued as rs780825688, COSV59700807; called by muse, mutect2, varscan2
- NCOR2 | c.2956dup p.R986Pfs*76 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | catalogued as rs746871841; called by mutect2, varscan2
- NDN | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.874); catalogued as COSV100086554; called by muse, mutect2, varscan2
- NDST4 | c.2101T>C p.Y701H | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99997043; called by muse, mutect2, varscan2
- NEB | c.18836A>G p.K6279R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99425246; called by muse, mutect2
- NECAB1 | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV101341033, COSV101341121; called by muse, mutect2
- NECAP1 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.935); catalogued as COSV100331615; called by muse, mutect2, varscan2
- NEDD9 | c.1637C>T p.T546I | Missense Mutation (SNP) | VAF 132/580 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101060881; called by muse, mutect2, varscan2
- NELFCD | c.1793T>C p.V598A (on ENST00000602795; = p.V580A on NM_198976.4) | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV99413661; called by muse, mutect2, varscan2
- NEU2 | c.909G>C p.Q303H | Missense Mutation (SNP) | VAF 224/290 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV99290640; called by muse, mutect2, varscan2
- NEXN | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as COSV99630465; called by muse, mutect2, varscan2
- NFAT5 | c.4247A>G p.Q1416R | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100590965; called by muse, mutect2, varscan2
- NFATC4 | c.1077G>T p.E359D | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.124); catalogued as COSV99147707; called by muse, mutect2, varscan2
- NFKBID | c.359C>T p.S120L (on ENST00000396901; = p.S272L on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 113/162 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs772624677, COSV100756489; called by muse, mutect2, varscan2
- NHS | c.1966G>T p.E656* | Nonsense Mutation (SNP) | VAF 244/317 reads (77%) | catalogued as COSV101196751, COSV66280789; called by muse, mutect2, varscan2
- NLRP14 | c.216G>C p.W72C | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100205203, COSV55065321; called by muse, mutect2, varscan2
- NPAP1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.097); catalogued as COSV61503881; called by muse, mutect2, varscan2
- NPY5R | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 78/110 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100642843, COSV58451589; called by muse, mutect2, varscan2
- NR2F2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 109/306 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67683763; called by muse, mutect2, varscan2
- NRAP | c.771G>T p.E257D | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV100748502; called by muse, mutect2
- NT5DC3 | c.761T>A p.I254N | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101230999; called by muse, mutect2
- NTM | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 90/234 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as COSV100869015; called by muse, mutect2, varscan2
- NUAK1 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99777147; called by muse, mutect2, varscan2
- NUAK1 | c.1259T>C p.V420A | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99777149; called by muse, mutect2
- NUDCD1 | c.454T>C p.W152R | Missense Mutation (SNP) | VAF 140/358 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99517391; called by muse, mutect2, varscan2
- NUF2 | c.607-2A>G p.X203_splice | Splice Site (SNP) | VAF 34/204 reads (17%) | catalogued as COSV99616662; called by muse, mutect2, varscan2
- NUP214 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845339; called by muse, mutect2, varscan2
- OR10A4 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 142/234 reads (61%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV101139489, COSV101139543; called by muse, mutect2, varscan2
- OR10C1 | c.711G>T p.K237N (on ENST00000622521; = p.K235N on NM_013941.3) | Missense Mutation (SNP) | VAF 93/795 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101010857, COSV65823638; called by muse, mutect2, varscan2
- OR10S1 | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101602492, COSV101602501, COSV73342692; called by muse, mutect2
- OR2M5 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 159/362 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV63546727; called by muse, mutect2, varscan2
- OR2T1 | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 131/345 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV100822333, COSV63542946; called by muse, mutect2, varscan2
- OR5A1 | c.766G>T p.G256W | Missense Mutation (SNP) | VAF 217/611 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118424; called by muse, mutect2, varscan2
- OR5D14 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 105/261 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.052); catalogued as COSV100162486; called by muse, mutect2, varscan2
- OR5F1 | c.294C>G p.F98L | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.993); catalogued as COSV53545361, COSV99558748; called by muse, mutect2
- OR5H14 | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV101454226; called by muse, mutect2, varscan2
- OR5L2 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101004359; called by muse, mutect2, varscan2
- OR8J3 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100040923; called by muse, mutect2, varscan2
- ORC3 | c.19T>A p.S7T | Missense Mutation (SNP) | VAF 33/384 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100006076; called by muse, mutect2
- OSBP | c.1664C>G p.S555C | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99803169; called by muse, mutect2
- OSGIN2 | c.1010A>T p.D337V | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475930833, COSV99858477; called by muse, mutect2
- OTOGL | c.5495A>G p.H1832R (on ENST00000547103; = p.H1823R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as COSV100087494; called by muse, mutect2, varscan2
- P2RX7 | c.892T>C p.Y298H | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1381960876, COSV99947472; called by muse, mutect2, varscan2
- P2RY4 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 74/94 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs147042327, COSV100997040; called by muse, mutect2, varscan2
- PADI6 | c.1816A>G p.K606E | Missense Mutation (SNP) | VAF 71/102 reads (70%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100639969; called by muse, mutect2, varscan2
- PAK2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 133/705 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1356174917, COSV59086136; called by muse, mutect2, varscan2
- PAK2 | c.1462A>G p.R488G | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59082089; called by muse, mutect2, varscan2
- PALB2 | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 138/339 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99848719; called by muse, mutect2, varscan2
- PARD3 | c.2594C>G p.T865R | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100401424; called by muse, mutect2, varscan2
- PARP8 | c.1225A>G p.R409G | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.637); catalogued as COSV99892058; called by muse, mutect2
- PAWR | c.638A>T p.Y213F | Missense Mutation (SNP) | VAF 115/322 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.404); catalogued as COSV100174302; called by muse, mutect2, varscan2
- PCDH11X | c.3245C>A p.S1082Y | Missense Mutation (SNP) | VAF 124/181 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV100013016; called by muse, mutect2, varscan2
- PCDH11Y | c.1583G>T p.G528V (on ENST00000400457 / NM_032973.2; = p.G517V on NM_032971.3) | Missense Mutation (SNP) | VAF 103/134 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53079031; called by muse, mutect2, varscan2
- PCDH15 | c.4934T>C p.L1645P | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs557722266, COSV100223738; called by muse, mutect2, varscan2
- PCDH19 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.052); catalogued as COSV99720239; called by muse, mutect2, varscan2
- PCDHB16 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 91/149 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554282166, COSV53358709, COSV99502359; called by muse, mutect2, varscan2
- PCDHB2 | c.529A>G p.N177D | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99523345; called by muse, mutect2, varscan2
- PCDHGA3 | c.2240G>T p.R747L | Missense Mutation (SNP) | VAF 149/250 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.614); catalogued as rs202194695, COSV54012605, COSV54025739; called by muse, mutect2, varscan2
- PCK2 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.477); catalogued as rs61737097, COSV53749514, COSV99394484; called by muse, mutect2, varscan2
- PDE5A | c.659G>A p.C220Y | Missense Mutation (SNP) | VAF 113/354 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.211); catalogued as rs200274828, COSV99308924; called by muse, mutect2, varscan2
- PDGFD | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100159935; called by muse, mutect2, varscan2
- PDK1 | c.934T>G p.L312V | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.149); catalogued as COSV99961392; called by muse, mutect2, varscan2
- PDX1 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 45/63 reads (71%) | catalogued as COSV101124101; called by muse, mutect2, varscan2
- PGM3 | c.304A>C p.M102L | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99392468; called by muse, mutect2
- PHF3 | c.5698C>G p.P1900A | Missense Mutation (SNP) | VAF 129/331 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV100013581; called by muse, mutect2, varscan2
- PIBF1 | c.1448A>G p.Q483R | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs202145606, COSV100411699; called by muse, mutect2, varscan2
- PKHD1L1 | c.8401G>A p.G2801S | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV101006549; called by muse, mutect2, varscan2
- PKN3 | c.2057A>G p.K686R | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99403769; called by muse, mutect2, varscan2
- PKN3 | c.2187G>T p.E729D | Missense Mutation (SNP) | VAF 236/579 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99403771; called by muse, mutect2, varscan2
- PLA2G4A | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100820613; called by muse, mutect2, varscan2
- PLA2R1 | c.2339A>G p.N780S | Missense Mutation (SNP) | VAF 99/162 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV99323170; called by muse, mutect2, varscan2
- PLCG2 | c.1857G>C p.E619D | Missense Mutation (SNP) | VAF 280/808 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.158); catalogued as COSV100842441; called by muse, mutect2, varscan2
- PLCH1 | c.3301G>C p.D1101H (on ENST00000340059 / NM_001130960.2; = p.D1093H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/618 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV100397458; called by muse, mutect2, varscan2
- PLCZ1 | c.1204T>C p.F402L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.903); catalogued as COSV99856588; called by muse, mutect2, varscan2
- PLS3 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 87/120 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV99171782; called by muse, mutect2, varscan2
- PLSCR4 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV100724274; called by muse, mutect2, varscan2
- POLA1 | c.3380G>T p.S1127I | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV100985634; called by muse, mutect2, varscan2
- POLQ | c.4289dup p.L1430Ffs*5 | Frame Shift Ins (INS) | VAF 33/209 reads (16%) | catalogued as rs755281591, COSV99951761; called by mutect2, varscan2
- POLR1B | c.1129C>G p.P377A | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.038); catalogued as COSV99638069; called by muse, mutect2, varscan2
- POLR3B | c.2159T>C p.V720A | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV99943603; called by muse, mutect2, varscan2
- POU1F1 | c.362C>A p.P121Q | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100622716; called by muse, mutect2, varscan2
- POU1F1 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100622717; called by muse, mutect2, varscan2
- PPP2R1B | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376765814; called by muse, mutect2, varscan2
- PPP4R1 | c.2645G>A p.R882Q (on ENST00000400556 / NM_001042388.3; = p.R865Q on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/411 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53280159; called by muse, mutect2
- PPP4R3A | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV100466242; called by muse, mutect2, varscan2
- PRDM8 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as rs867594284, COSV100325231; called by muse, mutect2, varscan2
- PRDX6 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.193); catalogued as COSV61165902; called by muse, mutect2, varscan2
- PRIM1 | c.393C>A p.C131* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV100590431; called by muse, mutect2, varscan2
- PRKD1 | c.2410C>A p.P804T | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV100120978; called by muse, mutect2, varscan2
- PRKG1 | c.545G>C p.G182A | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100908870, COSV64788247; called by muse, mutect2, varscan2
- PRKN | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1406898777, COSV100630137; called by muse, mutect2
- PRODH2 | c.1256T>C p.L419P (on ENST00000301175; = p.L343P on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99995381; called by muse, mutect2
- PRORP | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.045); catalogued as COSV99155968; called by muse, mutect2, varscan2
- PRRC2C | c.4643A>G p.Q1548R (on ENST00000367742; = p.Q1546R on NM_015172.4) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1219371503, COSV100145541; called by muse, varscan2
- PSMA1 | c.65T>A p.I22N | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101123685; called by muse, mutect2, varscan2
- PTPRS | c.5372A>G p.H1791R | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99511441; called by muse, mutect2
- PTTG1IP | c.168+2T>C p.X56_splice | Splice Site (SNP) | VAF 13/118 reads (11%) | catalogued as COSV100445922; called by muse, mutect2, varscan2
- PUS3 | c.1325T>C p.F442S | Missense Mutation (SNP) | VAF 126/402 reads (31%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.01); catalogued as COSV99917036; called by muse, mutect2, varscan2
- QARS1 | c.1730T>C p.V577A | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100070162; called by muse, mutect2
- QARS1 | c.1321A>G p.T441A | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV100070164; called by muse, mutect2, varscan2
- RAB22A | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 104/257 reads (40%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.536); catalogued as COSV54831402, COSV54833419, COSV99720456; called by muse, mutect2, varscan2
- RAB5B | c.605A>T p.H202L | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100822166; called by muse, mutect2, varscan2
- RAD51AP2 | c.1276dup p.T426Nfs*2 | Frame Shift Ins (INS) | VAF 16/72 reads (22%) | catalogued as rs759722299; called by mutect2, varscan2
- RAD51AP2 | c.782A>G p.Q261R | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV101208379; called by muse, varscan2
- RAD54B | c.1006T>G p.C336G | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100279965; called by muse, mutect2, varscan2
- RALY | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99865954; called by muse, mutect2, varscan2
- RANBP9 | c.1561A>G p.K521E | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV99163586; called by muse, mutect2, varscan2
- RASAL2 | c.722dup p.D242Gfs*4 | Frame Shift Ins (INS) | VAF 37/312 reads (12%) | catalogued as rs771909008; called by mutect2, varscan2
- RBM27 | c.2918A>T p.H973L | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99506374; called by muse, mutect2, varscan2
- RDH5 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99141818; called by muse, mutect2, varscan2
- RECQL | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59085230; called by muse, mutect2, varscan2
- RELCH | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395882884, COSV99902460; called by muse, mutect2, varscan2
- RELN | c.805G>T p.G269W | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100634193; called by muse, mutect2, varscan2
- RFX1 | c.2068G>T p.G690C | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV99586249; called by muse, mutect2, varscan2
- RHOT1 | c.631T>C p.F211L | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100447408; called by muse, mutect2
- RIC1 | c.1739A>T p.H580L | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.072); catalogued as COSV99317596; called by muse, mutect2, varscan2
- RING1 | c.517dup p.E173Gfs*21 | Frame Shift Ins (INS) | VAF 140/480 reads (29%) | catalogued as rs761874510; called by mutect2, varscan2
- RNF38 | c.1038T>G p.H346Q | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.194); catalogued as COSV99425213; called by muse, mutect2, varscan2
- RPL6 | c.310A>G p.T104A | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV99176154; called by muse, mutect2, varscan2
- RSRC1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 65/388 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs372306685; called by muse, mutect2, varscan2
- RTKN | c.1667G>A p.R556H (on ENST00000272430 / NM_001015055.2; = p.R543H on NM_033046.2) | Missense Mutation (SNP) | VAF 300/602 reads (50%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs201347198, COSV51967724; called by muse, mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as rs747510098; called by mutect2, varscan2
- RYR2 | c.3712C>T p.P1238S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100771778; called by muse, mutect2, varscan2
- RYR2 | c.12347A>G p.Q4116R | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs1191239112, COSV100771780; called by muse, mutect2, varscan2
- RYR3 | c.7969A>C p.K2657Q (on ENST00000389232; = p.K2658Q on NM_001036.6) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV101213187; called by muse, mutect2, varscan2
- SAGE1 | c.868A>G p.N290D | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100187584; called by muse, mutect2, varscan2
- SAGE1 | c.2625del p.V876Lfs*3 | Frame Shift Del (DEL) | VAF 16/25 reads (64%) | catalogued as COSV100187650; called by mutect2, varscan2
- SAMHD1 | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV99484175; called by muse, mutect2
- SCEL | c.1609G>T p.A537S (on ENST00000349847 / NM_144777.3; = p.A517S on NM_003843.4) | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.269); catalogued as COSV100583056; called by muse, mutect2, varscan2
- SCLT1 | c.1222T>C p.C408R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1211837234, COSV99828273; called by muse, mutect2, varscan2
- SCN10A | c.5779G>A p.G1927S | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.665); catalogued as COSV101479459; called by muse, mutect2
- SCN10A | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 9/125 reads (7%) | catalogued as rs1168396269, COSV71860734; called by muse, mutect2
- SCN9A | c.2504G>A p.R835Q (on ENST00000303354; = p.R824Q on NM_002977.3) | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs375375336; called by muse, mutect2, varscan2
- SCN9A | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 89/317 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs1389373425, COSV100313446; called by muse, mutect2, varscan2
- SCYL3 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 229/1113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63044388; called by muse, mutect2, varscan2
- SEC14L1 | c.1611+2T>A p.X537_splice | Splice Site (SNP) | VAF 44/109 reads (40%) | catalogued as COSV101171101, COSV101171153; called by muse, mutect2, varscan2
- SEC14L1 | c.1952G>T p.R651L | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV101171102; called by muse, mutect2, varscan2
- SEC24C | c.1067T>A p.L356* | Nonsense Mutation (SNP) | VAF 36/142 reads (25%) | catalogued as COSV100226998; called by muse, mutect2, varscan2
- SEC31B | c.1747T>C p.C583R | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100947371; called by muse, mutect2, varscan2
- SELPLG | c.1130C>G p.S377C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV57312766, COSV99947521; called by muse, mutect2, varscan2
- SEPTIN1 | c.737A>T p.Y246F (on ENST00000321367; = p.Y199F on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV100363127; called by muse, mutect2, varscan2
- SERINC3 | c.1048T>C p.Y350H | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV99667870; called by muse, mutect2, varscan2
- SERPINA10 | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100003908, COSV56229132; called by muse, mutect2, varscan2
- SETBP1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as rs187433533; called by muse, mutect2, varscan2
- SETD1A | c.3976G>A p.A1326T | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs756711740, COSV99353349; called by muse, mutect2, varscan2
- SH2B3 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.457); catalogued as rs1416067054, COSV57984990; called by muse, mutect2, varscan2
- SHPRH | c.2741T>A p.I914K | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51608624, COSV99262359; called by muse, mutect2, varscan2
- SHTN1 | c.873A>C p.E291D | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV99599178; called by muse, mutect2, varscan2
- SI | c.1160C>A p.T387N | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.841); catalogued as COSV100016304; called by muse, mutect2, varscan2
- SIK2 | c.796A>T p.K266* | Nonsense Mutation (SNP) | VAF 57/130 reads (44%) | catalogued as COSV100516338; called by muse, mutect2, varscan2
- SIM1 | c.912G>A p.W304* | Nonsense Mutation (SNP) | VAF 13/160 reads (8%) | catalogued as COSV53489138; called by muse, mutect2
- SLC12A4 | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99863149; called by muse, mutect2, varscan2
- SLC22A4 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV52358992, COSV99569465; called by muse, mutect2, varscan2
- SLC28A1 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 9/264 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1341701454, COSV99723025; called by muse, mutect2
- SLC28A3 | c.1830C>T p.G610= | Splice Region (SNP) | VAF 22/168 reads (13%) | catalogued as COSV100883286; called by muse, mutect2
- SLC35A4 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 77/125 reads (62%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1178644844, COSV100021398; called by muse, mutect2, varscan2
- SLC35F4 | c.998T>A p.V333E (on ENST00000339762 / NM_001352015.2; = p.V297E on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100334021; called by muse, varscan2
- SLC4A2 | c.298del p.Q100Rfs*145 | Frame Shift Del (DEL) | VAF 49/165 reads (30%) | catalogued as COSV59655753; called by mutect2, pindel, varscan2
- SLC7A14 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 90/403 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV99200648; called by muse, mutect2, varscan2
- SLC9A5 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100237381; called by muse, mutect2, varscan2
- SLCO2B1 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99214851; called by muse, mutect2, varscan2
- SLIT2 | c.1977-2A>G p.X659_splice | Splice Site (SNP) | VAF 50/69 reads (72%) | catalogued as COSV99885353; called by muse, mutect2, varscan2
- SLITRK3 | c.1615T>C p.F539L | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as COSV99579603; called by muse, mutect2
- SLITRK4 | c.721A>T p.I241F | Missense Mutation (SNP) | VAF 93/127 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100567414; called by muse, mutect2, varscan2
- SMARCA4 | c.1403G>T p.R468L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100758796; called by muse, mutect2, varscan2
- SMC1A | c.2879A>G p.E960G | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV59127456; called by muse, mutect2, varscan2
- SMG5 | c.2962A>G p.M988V | Missense Mutation (SNP) | VAF 65/289 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs989591809, COSV99431353; called by muse, mutect2, varscan2
- SMYD1 | c.133G>C p.D45H | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101352467, COSV70226181; called by muse, mutect2, varscan2
- SMYD1 | c.164G>A p.C55Y | Missense Mutation (SNP) | VAF 115/233 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768002293, COSV101352394; called by muse, mutect2, varscan2
- SORCS1 | c.2587G>T p.G863C | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99548045; called by muse, mutect2, varscan2
- SORCS3 | c.689T>C p.L230P | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100865390; called by muse, mutect2, varscan2
- SP100 | c.271-2A>G p.X91_splice | Splice Site (SNP) | VAF 37/125 reads (30%) | catalogued as COSV99893645; called by muse, mutect2, varscan2
- SPATS2 | c.24G>T p.K8N | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV100423288; called by muse, mutect2, varscan2
- SPEG | c.4004T>C p.L1335P | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100405015; called by muse, mutect2
- SPTA1 | c.2959G>A p.D987N | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100935189, COSV63757188; called by muse, mutect2
- SPTAN1 | c.4883C>A p.A1628D | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as COSV100823772; called by muse, mutect2, varscan2
- SPTAN1 | c.6455A>C p.E2152A | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.174); catalogued as COSV100823773; called by muse, mutect2
- SRPX | c.1139T>C p.V380A | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs1242182462, COSV100656146; called by muse, mutect2
- SRPX | c.959T>C p.M320T | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV100656148; called by muse, mutect2, varscan2
- SRRM2 | c.1866G>C p.R622S | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as COSV100071089; called by muse, mutect2, varscan2
- SRRM4 | c.1315T>A p.S439T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV57416143; called by muse, mutect2, varscan2
- SSC4D | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.69); PolyPhen benign (0.024); catalogued as COSV51882319; called by muse, mutect2, varscan2
- ST3GAL1 | c.292T>C p.Y98H | Missense Mutation (SNP) | VAF 36/84 reads (43%) | PolyPhen probably damaging (0.982); catalogued as COSV100172298; called by muse, mutect2
- STAB1 | c.2217_2218insA p.C740Mfs*9 | Frame Shift Ins (INS) | VAF 20/136 reads (15%) | catalogued as COSV100401959; called by mutect2, pindel, varscan2
- STK16 | c.828C>G p.D276E | Missense Mutation (SNP) | VAF 93/347 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99850688; called by muse, mutect2, varscan2
- STN1 | c.1062G>C p.Q354H | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs1353836308, COSV99830263; called by muse, mutect2, varscan2
- STX19 | c.778T>C p.Y260H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100115610; called by muse, mutect2
- STX1B | c.725A>G p.Y242C | Missense Mutation (SNP) | VAF 35/558 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV99288232; called by muse, mutect2
- STXBP5L | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56529637; called by muse, mutect2
- SYNE1 | c.21998T>C p.L7333S (on ENST00000367255 / NM_182961.4; = p.L7262S on NM_033071.3) | Missense Mutation (SNP) | VAF 99/269 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99571247; called by muse, mutect2, varscan2
- SYNE1 | c.15619G>C p.E5207Q (on ENST00000367255 / NM_182961.4; = p.E5136Q on NM_033071.3) | Missense Mutation (SNP) | VAF 143/362 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.156); catalogued as COSV99571251; called by muse, mutect2, varscan2
- SYNE2 | c.3137G>A p.G1046D | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV100648098; called by muse, mutect2, varscan2
- SYNJ1 | c.850T>A p.S284T | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100449465; called by muse, mutect2, varscan2
- SYT10 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 101/241 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV57339160, COSV99951665; called by muse, mutect2, varscan2
- TAF11 | c.622dup p.I208Nfs*26 | Frame Shift Ins (INS) | VAF 52/198 reads (26%) | catalogued as rs1385487890; called by mutect2, varscan2
- TARS3 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100254823; called by muse, mutect2, varscan2
- TAS2R39 | c.456G>T p.W152C | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV101489409; called by muse, mutect2, varscan2
- TAS2R50 | c.81A>G p.I27M | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101115143; called by muse, mutect2
- TAS2R50 | c.79A>T p.I27L | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV101115146, COSV101115188; called by muse, mutect2
- TBX22 | c.1196G>C p.S399T | Missense Mutation (SNP) | VAF 214/279 reads (77%) | SIFT tolerated (0.39); PolyPhen benign (0.272); catalogued as COSV100960868; called by muse, mutect2, varscan2
- TBX4 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53609332; called by muse, mutect2
- TBX6 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 7/103 reads (7%) | catalogued as COSV99661710; called by muse, mutect2
- TECTA | c.2485G>A p.D829N | Missense Mutation (SNP) | VAF 161/416 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0.076); catalogued as COSV99880327, COSV99880528; called by muse, mutect2, varscan2
- TENM1 | c.2241G>T p.W747C | Missense Mutation (SNP) | VAF 58/83 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100950411; called by muse, mutect2, varscan2
- TENT4A | c.1762C>G p.P588A | Missense Mutation (SNP) | VAF 104/147 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV100049102; called by muse, mutect2, varscan2
- TET2 | c.3256A>G p.T1086A | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1013733543, COSV99483636; called by muse, mutect2, varscan2
- TFR2 | c.1511A>G p.Y504C | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1211087, COSV99774624; called by muse, mutect2
- TG | c.6799C>A p.P2267T | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99601910; called by muse, mutect2, varscan2
- TGFB2 | c.594G>A p.W198* | Nonsense Mutation (SNP) | VAF 41/337 reads (12%) | catalogued as COSV100860306; called by muse, mutect2, varscan2
- TGIF1 | c.601A>G p.K201E (on ENST00000330513 / NM_001374396.1; = p.K221E on NM_003244.4) | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.325); catalogued as COSV100394904; called by muse, mutect2
- TGIF2LY | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 99/125 reads (79%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.778); catalogued as COSV100339665; called by muse, mutect2, varscan2
- TGM6 | c.1664T>A p.L555Q | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99171879; called by muse, mutect2, varscan2
- THADA | c.221C>G p.T74S | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV101264110; called by muse, mutect2, varscan2
- TLE6 | c.1501G>A p.D501N (on ENST00000246112 / NM_001143986.2; = p.D378N on NM_024760.3) | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.797); catalogued as COSV99504506; called by muse, mutect2, varscan2
- TLN2 | c.1058A>G p.E353G | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV100169528; called by muse, mutect2, varscan2
- TLR4 | c.93+2T>C p.X31_splice | Splice Site (SNP) | VAF 37/98 reads (38%) | catalogued as COSV100790672; called by muse, mutect2, varscan2
- TLR5 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV100643337; called by muse, mutect2, varscan2
- TM4SF4 | c.36dup p.T13Dfs*13 | Frame Shift Ins (INS) | VAF 30/198 reads (15%) | catalogued as rs747355584; called by mutect2, varscan2
- TMEM196 | c.534G>C p.R178S (on ENST00000405844 / NM_001363562.2; = p.E154Q on NM_152774.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); catalogued as COSV101337508, COSV68254688; called by muse, mutect2
- TMEM245 | c.2382C>G p.I794M | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs2919822, COSV101002402; called by muse, mutect2, varscan2
- TMEM248 | c.856T>C p.C286R | Missense Mutation (SNP) | VAF 138/356 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100447244; called by muse, mutect2, varscan2
- TMEM87A | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV101100486; called by muse, mutect2, varscan2
- TNFRSF10B | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99375495; called by muse, mutect2, varscan2
- TNFRSF11A | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.044); catalogued as COSV54021763, COSV99500359; called by muse, mutect2, varscan2
- TNRC18 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101259484; called by muse, mutect2
- TOGARAM1 | c.1534T>C p.S512P | Missense Mutation (SNP) | VAF 131/351 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV100753175; called by muse, mutect2, varscan2
- TOMM34 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 38/546 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.034); catalogued as COSV65689606; called by muse, mutect2
- TPBG | c.1094T>C p.L365P | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63882584; called by muse, mutect2
- TRERF1 | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 86/338 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV100551096; called by muse, mutect2, varscan2
- TREX1 | c.902T>C p.V301A (on ENST00000625293 / NM_033629.6; = p.V291A on NM_007248.5) | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV99604094; called by muse, mutect2
- TRHDE | c.2430T>C p.H810= | Splice Region (SNP) | VAF 29/85 reads (34%) | catalogued as COSV99671587; called by muse, mutect2, varscan2
- TRIM56 | c.1648T>C p.C550R | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV100047501; called by muse, mutect2
- TRIM6 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 92/151 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99546565; called by muse, mutect2, varscan2
- TRIM9 | c.1333A>T p.I445F | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV100031772; called by muse, mutect2
- TRIP11 | c.5906C>A p.A1969D | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99970890; called by muse, mutect2, varscan2
- TRIP13 | c.991T>G p.Y331D | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV99386463; called by muse, mutect2, varscan2
- TRMT10B | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 101/120 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV99956102; called by muse, mutect2, varscan2
- TRMT61A | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs1425354966, COSV100149407; called by muse, mutect2
- TRPM3 | c.718C>A p.H240N (on ENST00000357533 / NM_001366142.2; = p.H85N on NM_020952.6) | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV100625115; called by muse, mutect2, varscan2
- TRPM5 | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV99330314; called by muse, varscan2
- TTC14 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV99869833; called by muse, mutect2, varscan2
- TTC3 | c.4692del p.E1565Kfs*6 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs778730652; called by mutect2, varscan2
- TTC8 | c.472A>G p.T158A (on ENST00000338104 / NM_001288781.1; = p.T168A on NM_144596.4) | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.086); catalogued as COSV100581503; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | catalogued as rs768996038, COSV57882295; called by mutect2, pindel, varscan2
- TTLL7 | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99552667; called by muse, mutect2
- TTN | c.89229T>A p.S29743R (on ENST00000591111; = p.S22319R on NM_003319.4) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | PolyPhen possibly damaging (0.447); catalogued as COSV100620413; called by muse, mutect2, varscan2
- TTN | c.63369G>A p.W21123* (on ENST00000591111; = p.W13699* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100620420; called by muse, mutect2, varscan2
- TTR | c.373T>C p.Y125H | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52701143; called by muse, mutect2, varscan2
- TUBB6 | c.457A>T p.S153C | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99302042; called by muse, mutect2, varscan2
- UBR5 | c.8170A>G p.T2724A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.298); catalogued as COSV99641485; called by muse, mutect2, varscan2
- UCHL5 | c.707_709del p.A236del | In Frame Del (DEL) | VAF 13/66 reads (20%) | catalogued as rs1488048601; called by mutect2, pindel, varscan2
- UGT2B15 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.335); catalogued as COSV100592384; called by muse, mutect2, varscan2
- UGT3A2 | c.364A>G p.S122G | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs368967368; called by muse, mutect2, varscan2
- UHRF1 | c.1620G>T p.K540N (on ENST00000612630 / NM_001290050.1; = p.K553N on NM_013282.4) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99503599; called by muse, mutect2, varscan2
- UNC5D | c.2098T>C p.S700P | Missense Mutation (SNP) | VAF 134/362 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.196); catalogued as COSV99776973; called by muse, mutect2, varscan2
- UNC79 | c.5512A>G p.R1838G (on ENST00000393151 / NM_001346218.2; = p.R1661G on NM_020818.5) | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99828717; called by muse, mutect2, varscan2
- UNC79 | c.5957T>A p.V1986D (on ENST00000393151 / NM_001346218.2; = p.V1809D on NM_020818.5) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as COSV99828721; called by muse, mutect2, varscan2
- UROC1 | c.1898G>T p.R633L | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99331829; called by muse, mutect2, varscan2
- USF3 | c.878T>C p.L293S | Missense Mutation (SNP) | VAF 67/336 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as COSV100325515; called by muse, mutect2, varscan2
- USH1G | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs866052000, COSV100140545; called by muse, mutect2, varscan2
- USH2A | c.5774C>T p.T1925I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100238337; called by muse, mutect2, varscan2
- USP26 | c.1603A>G p.N535D | Missense Mutation (SNP) | VAF 141/189 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100896690; called by muse, mutect2, varscan2
- USP6 | c.3752dup p.S1252Qfs*12 | Frame Shift Ins (INS) | VAF 32/78 reads (41%) | catalogued as rs754083634; called by mutect2, varscan2
- USP9X | c.7414G>T p.E2472* | Nonsense Mutation (SNP) | VAF 75/102 reads (74%) | catalogued as COSV100199709; called by muse, mutect2, varscan2
- VIRMA | c.128T>A p.I43K | Missense Mutation (SNP) | VAF 38/413 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99888826; called by muse, mutect2
- VPREB1 | c.68T>A p.L23Q | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100164852; called by muse, mutect2, varscan2
- VPS13C | c.9674T>C p.V3225A (on ENST00000644861 / NM_020821.3; = p.V3182A on NM_017684.5) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99829249; called by muse, mutect2
- VPS72 | c.513A>T p.E171D | Missense Mutation (SNP) | VAF 188/940 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100614514; called by muse, mutect2, varscan2
- VSIG8 | c.562T>A p.Y188N | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100928818; called by muse, mutect2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 30/127 reads (24%) | catalogued as rs756173793; called by mutect2, varscan2
- WDR25 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100091991; called by muse, mutect2, varscan2
- WDR26 | c.1652G>T p.S551I (on ENST00000414423 / NM_001379403.1; = p.S451I on NM_025160.7) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV99691344; called by muse, mutect2, varscan2
- WNK1 | c.5063T>C p.V1688A (on ENST00000315939 / NM_018979.4; = p.V1441A on NM_014823.3) | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100267866; called by muse, mutect2, varscan2
- WNK2 | c.5907dup p.N1970Qfs*47 (on ENST00000297954 / NM_001282394.1; = p.N1933Qfs*47 on NM_006648.3) | Frame Shift Ins (INS) | VAF 10/21 reads (48%) | catalogued as rs1448689824; called by mutect2, varscan2
- WNT3 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs778399124, COSV99843335; called by muse, mutect2, varscan2
- ZBTB11 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.484); catalogued as COSV100465609; called by muse, mutect2, varscan2
- ZBTB20 | c.2075dup p.A693Cfs*33 (on ENST00000474710 / NM_001164342.2; = p.A620Cfs*33 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 72/442 reads (16%) | catalogued as rs777745612; called by mutect2, varscan2
- ZBTB22 | c.1278C>G p.I426M | Missense Mutation (SNP) | VAF 114/496 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV56466604, COSV99802352; called by muse, mutect2, varscan2
- ZBTB7A | c.1046T>C p.M349T | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs569620079, COSV100475769; called by muse, mutect2, varscan2
- ZC3H11A | c.35del p.F12Sfs*20 | Frame Shift Del (DEL) | VAF 46/124 reads (37%) | catalogued as rs768425662; called by mutect2, varscan2
- ZC3H11A | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV100142498; called by muse, mutect2, varscan2
- ZCRB1 | c.552dup p.W185Mfs*13 | Frame Shift Ins (INS) | VAF 18/58 reads (31%) | catalogued as rs751992496; called by mutect2, varscan2
- ZDHHC14 | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV58193355; called by muse, mutect2, varscan2
- ZFHX4 | c.7607C>A p.P2536H | Missense Mutation (SNP) | VAF 130/321 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99264922; called by muse, mutect2, varscan2
- ZIC4 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 124/179 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as rs1353915619, COSV67173829, COSV67174472; called by muse, mutect2, varscan2
- ZNF131 | c.279A>T p.K93N | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100185589; called by muse, mutect2, varscan2
- ZNF184 | c.2167G>T p.E723* | Nonsense Mutation (SNP) | VAF 96/264 reads (36%) | catalogued as rs201499940, COSV99279832; called by muse, mutect2, varscan2
- ZNF205 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 127/301 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54621874; called by muse, mutect2, varscan2
- ZNF217 | c.822dup p.S275Ifs*4 | Frame Shift Ins (INS) | VAF 124/393 reads (32%) | catalogued as rs1250273095; called by mutect2, pindel, varscan2
- ZNF236 | c.1381dup p.M461Nfs*104 | Frame Shift Ins (INS) | VAF 40/109 reads (37%) | catalogued as rs769237443; called by mutect2, varscan2
- ZNF277 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 133/370 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as rs1211027420, COSV100702493; called by muse, mutect2, varscan2
- ZNF277 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100702494; called by muse, mutect2, varscan2
- ZNF430 | c.400A>G p.R134G | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.423); catalogued as COSV99841870; called by muse, mutect2, varscan2
- ZNF440 | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1457479029, COSV100407631; called by muse, mutect2
- ZNF500 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs751834995, COSV99556426; called by muse, mutect2, varscan2
- ZNF518A | c.3759A>T p.K1253N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1554886825, COSV100283608, COSV60150226; called by muse, mutect2, varscan2
- ZNF519 | c.1258A>G p.T420A | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV101645578; called by muse, mutect2
- ZNF638 | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 105/378 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100039275, COSV52482559; called by muse, mutect2, varscan2
- ZNF775 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs370555977; called by muse, mutect2, varscan2
- ZNF831 | c.3073dup p.D1025Gfs*9 | Frame Shift Ins (INS) | VAF 32/77 reads (42%) | catalogued as rs775554241; called by mutect2, varscan2
- ZRANB3 | c.3220C>T p.R1074* | Nonsense Mutation (SNP) | VAF 18/30 reads (60%) | catalogued as rs780636487, COSV99924107; called by muse, varscan2
- ZSWIM4 | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 96/277 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs780947938, COSV99585101; called by muse, mutect2, varscan2
- AATF | c.1512dup p.V505Sfs*3 | Frame Shift Ins (INS) | VAF 26/69 reads (38%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.459dup p.E154* | Frame Shift Ins (INS) | VAF 40/118 reads (34%) | called by mutect2, varscan2
- ALG10 | c.800T>C p.F267S | Missense Mutation (SNP) | VAF 15/485 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP30 | c.3210dup p.R1071Qfs*7 (on ENST00000368013 / NM_001025598.2; = p.R860Qfs*7 on NM_181720.3) | Frame Shift Ins (INS) | VAF 78/427 reads (18%) | called by mutect2, pindel, varscan2
- ARMC5 | c.682del p.Q228Sfs*27 | Frame Shift Del (DEL) | VAF 51/133 reads (38%) | called by mutect2, varscan2
- B4GALNT3 | c.1176T>G p.C392W | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BAZ2B | c.6275A>T p.K2092I | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- BBOF1 | c.518_519del p.T173Rfs*9 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by pindel, varscan2
- BTBD7 | c.2778dup p.H927Tfs*21 | Frame Shift Ins (INS) | VAF 54/281 reads (19%) | called by mutect2, pindel, varscan2
- CACNA1I | c.2803del p.R935Dfs*23 | Frame Shift Del (DEL) | VAF 33/110 reads (30%) | called by mutect2, pindel, varscan2
- CASZ1 | c.232dup p.R78Pfs*55 | Frame Shift Ins (INS) | VAF 90/193 reads (47%) | called by mutect2, pindel, varscan2
- CCDC138 | c.652C>A p.L218M | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.25); called by muse, mutect2
- CCDC30 | c.1656dup p.V553Sfs*12 (on ENST00000340612; = p.V510Sfs*12 on NM_001080850.3) | Frame Shift Ins (INS) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- CEP128 | c.1897dup p.M633Nfs*17 | Frame Shift Ins (INS) | VAF 81/279 reads (29%) | called by mutect2, varscan2
- CEP128 | c.1896delinsAA p.M633Nfs*17 | Frame Shift Ins (INS) | VAF 64/337 reads (19%) | called by mutect2*, pindel, varscan2*
- CEP250 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2
- CIDEA | c.190del p.D64Mfs*37 | Frame Shift Del (DEL) | VAF 52/168 reads (31%) | called by mutect2, pindel, varscan2
- CLK2 | c.588G>C p.K196N (on ENST00000368361 / NM_001294339.2; = p.K195N on NM_003993.4) | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX3X | c.1966dup p.V656Gfs*2 (on ENST00000399959; = p.V657Gfs*2 on NM_001356.5) | Frame Shift Ins (INS) | VAF 57/103 reads (55%) | called by mutect2, pindel, varscan2
- DNAJC2 | c.590del p.N197Mfs*8 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, varscan2
- E2F3 | c.529dup p.T177Nfs*4 | Frame Shift Ins (INS) | VAF 52/232 reads (22%) | called by mutect2, pindel, varscan2
- EMG1 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- ESPL1 | c.6318dup p.G2107Wfs*46 | Frame Shift Ins (INS) | VAF 66/201 reads (33%) | called by mutect2, pindel, varscan2
- FAM111A | c.970del p.E324Kfs*14 | Frame Shift Del (DEL) | VAF 38/130 reads (29%) | called by mutect2, pindel, varscan2
- FAT1 | c.9772del p.D3258Ifs*12 | Frame Shift Del (DEL) | VAF 38/76 reads (50%) | called by mutect2, pindel, varscan2
- FBXO33 | c.887_888del p.L296Hfs*5 | Frame Shift Del (DEL) | VAF 94/278 reads (34%) | called by mutect2, pindel, varscan2
- FBXO38 | c.-1_10del | Translation Start Site (DEL) | VAF 23/54 reads (43%) | called by mutect2, pindel, varscan2
- FBXO38 | c.2472dup p.S825Vfs*7 | Frame Shift Ins (INS) | VAF 26/60 reads (43%) | called by mutect2, pindel, varscan2
- FGL2 | c.156_157insT p.G53Wfs*39 | Frame Shift Ins (INS) | VAF 120/408 reads (29%) | called by mutect2, pindel, varscan2
- FXR1 | c.371dup p.N124Kfs*5 | Frame Shift Ins (INS) | VAF 36/174 reads (21%) | called by mutect2, varscan2
- GPR89A | c.54dup p.G19Wfs*13 | Frame Shift Ins (INS) | VAF 34/176 reads (19%) | called by mutect2, varscan2
- GTF3C2 | c.2190dup p.A731Cfs*26 | Frame Shift Ins (INS) | VAF 110/273 reads (40%) | called by mutect2, pindel, varscan2
- H2BC7 | c.38dup p.S15Lfs*14 | Frame Shift Ins (INS) | VAF 120/342 reads (35%) | called by mutect2, pindel, varscan2
- HPS3 | c.793dup p.S265Kfs*2 | Frame Shift Ins (INS) | VAF 38/200 reads (19%) | called by mutect2, pindel, varscan2
- IGLV2-33 | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 101/857 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF3 | c.2368A>G p.S790G (on ENST00000369486 / NM_001007237.3; = p.S810G on NM_001542.4) | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2
- IMMT | c.923_924del p.V308Dfs*2 | Frame Shift Del (DEL) | VAF 23/133 reads (17%) | called by pindel, varscan2
- KIF20B | c.5452dup p.T1818Nfs*13 (on ENST00000371728 / NM_001284259.2; = p.T1778Nfs*13 on NM_016195.4) | Frame Shift Ins (INS) | VAF 33/131 reads (25%) | called by mutect2, pindel, varscan2
- LHFPL1 | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.093); called by muse, mutect2
311 further variants in this file (42 protein-altering or splice-affecting, 241 silent, 28 other) are not listed here.
